Gene-level copy-number profile of specimen HCM-CSHL-0383-C18-85A from HCMI case HCM-CSHL-0383-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 51.4 years (18,766 days).
Specimen HCM-CSHL-0383-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1905d696-304b-4a5b-8590-ea5bd8a5e05e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0383-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,865 have no estimate.
https://portal.gdc.cancer.gov/files/e5a831ac-6281-40e8-af8b-fd8ab4983b4f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 159; copy number 2: 24,329; copy number 3: 23,467; copy number 4: 6,708; copy number 5: 2,783; copy number 6: 330; copy number 7: 853; copy number 8: 120; copy number 9: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 982 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–144,305,180, 36 genes, copy number 7: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1.
- chr4:68,509,441–68,616,137, 4 genes, copy number 7: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr4:68,646,597–68,670,652, 1 gene, copy number 7: UGT2B15.
- chr10:80,271,820–80,646,560, 9 genes, copy number 9: MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14, AC021028.1, SH2D4B.
- chr20:22,220,554–35,216,240, 275 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:35,771,974–48,849,458, 317 genes, copy number 7 (broad region; genes not listed).
- chr20:49,293,394–53,504,314, 79 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:53,936,777–54,070,594, 1 gene, copy number 7 (within-gene range 6–7): BCAS1.
- chr20:54,068,408–64,327,972, 260 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 102. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
